Surgical pathology report (de-identified scan), TCGA case TCGA-B1-A47O, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B1-A47O-01A (Primary Tumor).

Collection Date:

FINAL DIAGNOSIS:

KIDNEY, RIGHT, PARTIAL NEPHRECTOMY—

- PAPILLARY RENAL CELL CARCINOMA, FAVOR TYPE 2, MAXIMAL FUHRMAN NUCLEAR GRADE 3 OUT OF 4, SEE COMMENT.
- TUMOR IS LIMITED TO THE KIDNEY AND MEASURES 5.6 x 5.0 x 4.0 CM.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- NO VASCULAR INVASION IS IDENTIFIED
- PATHOLOGIC TNM STAGE: pT1b NX MX
- PERITUMORAL NON-NEOPLASTIC KIDNEY WITH INTERSTITIAL INFLAMMATION AND SCATTERED SCLEROTIC GLOMERULI.

COMMENT:

The tumor cells show prominent eosinophilia and focal areas of necrosis. The Fuhrman nuclear grade ranges between 2 and 3. Some of the Fuhrman grade 2 areas with fibrohistiocytic cores resemble type 1 papillary renal cell carcinoma, but overall a diagnosis of type 2 papillary renal cell carcinoma is favored.

Immunohistochemical stains are performed with adequate controls and demonstrate that the tumor cells are strongly positive for p504s and AE1/3 and show focal / patchy positivity for CK7, CA9, and EMA. These findings support the above diagnosis.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY KIDNEY TUMORS

SPECIMEN TYPE: Partial nephrectomy
LATERALITY: Right
TUMOR SITE: Not specified
FOCALITY: Unifocal
TUMOR SIZE: Greatest dimension: 5.6 cm
Additional dimensions: 5.0 x 4.0 cm

MACROSCOPIC EXTENT OF TUMOR: Tumor limited to kidney

HISTOLOGIC TYPE: Papillary renal cell carcinoma

HISTOLOGIC GRADE (Fuhrman Nuclear Grade): G3

PATHOLOGIC STAGING (pTNM): pT1b
pNX

Number of regional lymph nodes examined: 0

PMX

MARGINS: Margins uninvolved by invasive carcinoma

ADRENAL GLAND: Not present

LYMPH-VASCULAR INVASION (LVI): Absent/not identified

ADDITIONAL PATHOLOGIC FINDINGS: None identified

ICD-O-3
carcinoma, papillary renal cell 8260/3
Site: Kidney, nos C64.9

fw
9/27/12

fw
9/27/12

Source: NCI Genomic Data Commons file 04f4f1f6-a9d4-4777-8956-087206d13196 (TCGA-B1-A47O.F0519EDE-C458-43C6-BD3F-4E67059EBFCE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).